Gene-level copy-number profile of tumor specimen TCGA-12-0662-01A from TCGA case TCGA-12-0662, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.2 years (18,717 days).
Specimen TCGA-12-0662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.815c45fc-890c-4371-af08-64b91337cb0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0662-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e3bf4c6-5fcf-4d4e-9628-1630c02c048c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 9,921; copy number 2: 42,193; copy number 3: 6,989; copy number 4: 681; copy number 9: 19; copy number 30: 11; copy number 32: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0662-01A-01D-0333-01): tumor purity 0.69, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,340,797–48,341,330, 1 gene: AL392048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,057,641–174,378,005, 3 genes, copy number 9: RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 9: RN7SKP40.
- chr3:181,534,177–182,368,256, 15 genes, copy number 9 (within-gene range 2–9): AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1.
- chr7:54,621,025–55,344,958, 13 genes, copy number 30–32: RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.

Autosomal genes at a single copy (total copy number 1): 7,540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
